Somatic mutation profile of tumor specimen TCGA-QR-A706-01A (aliquot TCGA-QR-A706-01A-11D-A35D-08) from TCGA case TCGA-QR-A706, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 50.9 years (18,585 days).
Specimen TCGA-QR-A706-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8632ae87-dc92-4e1b-951a-8bf9387dde24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A706-10A (Blood Derived Normal), aliquot TCGA-QR-A706-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c1bea5a-b5c0-49de-b7e1-67cb661538b1

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GBA | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM057095; called by muse, mutect2, varscan2
- TRPM1 | c.1234G>T p.A412S | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV56643020; called by muse, mutect2
- ABCA9 | c.4102C>T p.P1368S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C17orf80 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
